EXCEPTIONAL_RESPONDERS case ER-AFFX — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c70f478a-0f6e-4eca-a5d1-731739963726

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1966; Vital status: Dead; Days to death: 1,029 days (2.8 years); Year of death: 2015.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Cardia, NOS; Site of resection or biopsy: Cardia, NOS; Classification of tumor: primary; Age at diagnosis: 46.8 years (17,110 days); Year of diagnosis: 2013; AJCC pathologic stage: Stage IV; Prior malignancy: no; Days to last follow up: 579 days (1.6 years); Days to best overall response: 185 days; Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Fluorouracil; Days to treatment start: 19 days; Days to treatment end: 272 days.
   Treatment given: Therapeutic agents: Leucovorin Calcium + Oxaliplatin; Days to treatment start: 19 days; Days to treatment end: 270 days.
   Treatment given: Therapeutic agents: Trastuzumab; Days to treatment start: 20 days; Days to treatment end: 935 days (2.6 years).

Follow-up (1 entry)
- Days to follow up: 579 days (1.6 years); Disease response: Clinical Progression; Progression or recurrence: Yes; Days to progression: 579 days (1.6 years); Days progression-free: 412 days (1.1 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-AFFX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: FFPE.
  Slide ER-AFFX-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 65; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 35; Percent lymphocyte infiltration: 4; Percent monocyte infiltration: 4; Percent neutrophil infiltration: 6.
